Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0MT, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0MT-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: ILIAC LYMPH NODES, LEFT EXTERNAL, PELVIC AND PERI-AORTIC LYMPH NODE DISSECTION - TWO LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/2).

PART 2: LYMPH NODES, LEFT OBTURATOR, PELVIC AND PERIAORTIC LYMPH NODE DISSECTION - NO LYMPH NODES WERE IDENTIFIED (0/0).

PART 3: COMMON ILIAC LYMPH NODES, LEFT, PELVIC AND PERI-AORTIC LYMPH NODE DISSECTION- NO LYMPH NODES WERE IDENTIFIED (0/0).

PART 4: PERIAORTIC LYMPH NODES, LEFT, PELVIC AND PERIAORTIC LYMPH NODE DISSECTION - NO LYMPH NODES WERE IDENTIFIED (0/0).

PART 5: EXTERNAL ILIAC LYMPH NODE AND OBTURATOR, RIGHT, PELVIC AND PERIAORTIC LYMPH NODE DISSECTION - ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 6: PERIAORTIC LYMPH NODE, RIGHT, PELVIC AND PERIAORTIC LYMPH NODE DISSECTION - ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 7: COMMON ILIAC LYMPH NODE, RIGHT, PELVIC AND PERIAORTIC LYMPH NODE DISSECTION - TWO LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/2).

PART 8: UTERUS AND CERVIX (124 GRAMS) WITH BILATERAL ADNEXA, LAPAROSCOPIC ASSISTED VAGINAL HYSTERECTOMY -

- A. MODERATELY DIFFERENTIATED ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE (NOS), NUCLEAR GRADE 2, FIGO GRADE 2.
- B. THE TUMOR INVADES UP TO 25% OF THE MYOMETRIAL THICKNESS (0.5 CM INVASION OF 2.5 CM THICK MYOMETRIUM)
- C. NO LYMPHOVASCULAR INVASION IDENTIFIED.
- D. LEIOMYOMA, 0.4 CM.
- E. BILATERAL OVARIES WITH TUBO-OVARIAN ADHESION, FREE OF CARCINOMA.

F. BILATERAL FALLOPIAN TUBES WITH PARATUBAL CYSTS, FREE OF CARCINOMA.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE: Endometrioid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Moderately differentiated (FIGO 2)

ARCHITECTURAL GRADE: Moderately differentiated

NUCLEAR GRADE: Grade 2

TUMOR SIZE: Maximum dimension: 3.0 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 0 %, Posterior endomyometrium: 75 %

DEPTH OF INVASION**: Less than 1/2 thickness of myometrium

ANGIOLYMPHATIC INVASION: No

OTHER: (epithelial, smooth muscle, others), Leiomyoma

LYMPH NODES POSITIVE: Number of lymph nodes positive:: 0

LYMPH NODES EXAMINED: Total number of lymph nodes examined: 6

EXTRANODAL EXTENSION: No

T STAGE, PATHOLOGIC: pT1b

N STAGE, PATHOLOGIC: pN0

M STAGE, PATHOLOGIC: pMX

FIGO STAGE: IB

1CD-0-3

adenocarcinoma, endometrioid, nos 8380/3
Site: Endometrium C54.1 lw 5/3/11

Source: NCI Genomic Data Commons file 12ecdd04-aae0-4e4a-bc67-7d546d4e6efa (TCGA-BG-A0MT.89610F48-AC0D-431D-8A9E-FC9E51CF8FC0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).